CCDI case PBBXGW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/607ade7e-e7fc-499e-ad9a-7e9b13836ed4

Demographics
Sex at birth: female; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.5 years (1,285 days).

Biospecimens (3 samples)
- Sample 0DJXPC: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJXPR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DJXRK: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
